Gene-level copy-number profile of tumor specimen TCGA-DX-A48L-01A from TCGA case TCGA-DX-A48L, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.6 years (18,113 days).
Specimen TCGA-DX-A48L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5c98c4ff-d346-44c5-9908-7452359c5396.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A48L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d38a0f4-edf2-442d-8100-2af3b877f003

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 86; copy number 2: 8,865; copy number 3: 13,571; copy number 4: 30,149; copy number 5: 4,571; copy number 6: 1,844; copy number 8: 340; copy number 9: 120; copy number 18: 47; copy number 27: 121; copy number 39: 70; copy number 47: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A48L-01A-11D-A306-01): tumor purity 0.92, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,539,692–232,860,605, 13 genes: CHRNG, TIGD1, MIR5001, EIF4E2, AC073254.1, EFHD1, RN7SL359P, GIGYF2, EEF1B2P7, AC064852.1, KCNJ13, RNU6-107P, Y_RNA.
- chr17:5,019,214–5,191,868, 10 genes: KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2, ZFP3, ZNF232, ZNF232-AS1, USP6, AC012146.3, ZNF594.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 361 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:7,717,354–18,736,118, 361 genes, copy number 9–47 (within-gene range 2–47) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
